Somatic mutation profile of tumor specimen TCGA-A2-A1G1-01A (aliquot TCGA-A2-A1G1-01A-21D-A13L-09) from TCGA case TCGA-A2-A1G1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 85.5 years (31,223 days).
Specimen TCGA-A2-A1G1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 223968d7-0e65-4106-b8ce-894764e78ef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1G1-10A (Blood Derived Normal), aliquot TCGA-A2-A1G1-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e3d944b-139b-4470-93bd-3c236c6d4660

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Splice Site 2, Frame Shift Del 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 18/36 reads (50%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AOX1 | c.498+3_498+6del p.X166_splice | Splice Site (DEL) | VAF 8/47 reads (17%) | catalogued as rs1266609734; called by pindel, varscan2
- BTG3 | c.428A>C p.H143P | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.975); catalogued as COSV100336201; called by muse, mutect2, varscan2
- CENPK | c.652A>T p.I218F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV54469094; called by muse, mutect2, varscan2
- CORO2A | c.1367A>C p.H456P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59664200; called by muse, mutect2, varscan2
- CREBBP | c.2114A>G p.N705S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.351); catalogued as rs1474330488, COSV52134929; called by muse, mutect2, varscan2
- FTSJ3 | c.1871G>T p.S624I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.925); catalogued as COSV100834798; called by mutect2, varscan2
- MAP3K1 | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV68125955; called by muse, mutect2, varscan2
- MCAM | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765792211, COSV50682975; called by muse, mutect2, varscan2
- MXRA5 | c.819G>T p.M273I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54244461; called by muse, mutect2, varscan2
- OR14A16 | c.706T>G p.Y236D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100713641; called by muse, mutect2
- PHKA2 | c.3609C>A p.S1203R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66055453, COSV66055475; called by muse, mutect2, varscan2
- PTPRZ1 | c.4862A>G p.H1621R | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV66442586; called by muse, mutect2, varscan2
- SF3B2 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1286103842, COSV59429563; called by muse, mutect2, varscan2
- SLC41A3 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs866479284, COSV59989654; called by muse, mutect2, varscan2
- TRIB2 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50228175; called by muse, mutect2, varscan2
- TSPAN12 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56081199; called by muse, mutect2, varscan2
- TTN | c.50074G>A p.E16692K (on ENST00000591111; = p.E9268K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | PolyPhen possibly damaging (0.652); catalogued as COSV100588257; called by muse, mutect2
- TTN | c.49458G>C p.G16486= (on ENST00000591111; = p.G9062= on NM_003319.4) | Splice Region (SNP) | VAF 19/71 reads (27%) | catalogued as COSV60239317; called by muse, mutect2, varscan2
- XIRP2 | c.3919G>T p.V1307L (on ENST00000628543; = p.V1482L on NM_152381.6) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV54722367; called by muse, mutect2, varscan2
- ZNF711 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99340531; called by muse, mutect2
- GABRP | c.1187_1191del p.R396Qfs*7 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- MRPS7 | c.456_457del p.C152* | Frame Shift Del (DEL) | VAF 13/66 reads (20%) | called by pindel, varscan2
- RNF215 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2
- WDR12 | c.-1_21del | Translation Start Site (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- ATPAF1 | c.525C>T p.V175= (on ENST00000574428; = p.V198= on NM_022745.4) | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV61305454; called by muse, mutect2, varscan2
- KRT31 | c.954C>A p.I318= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as COSV52437161; called by muse, mutect2, varscan2
- MAP10 | c.2043G>A p.P681= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs756863938, COSV101406407; called by muse, mutect2
- MOCOS | c.1041G>A p.Q347= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV54345862; called by muse, mutect2
- NFIB | c.411G>C p.L137= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV66621173; called by muse, mutect2, varscan2
- SEPHS1 | c.309G>A p.A103= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs201414633, COSV59259917; called by muse, mutect2, varscan2
- ZBTB38 | c.426A>C p.G142= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV58543495; called by muse, mutect2, varscan2
